Gene-level copy-number profile of tumor specimen ALCH-B2D8-TTP1-A from ALCHEMIST case ALCH-B2D8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,065 days).
Specimen ALCH-B2D8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 13370f72-a7f3-416e-9f75-8415b4f3df5e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2D8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/04393917-ebf7-46da-aeb3-b0ca642665e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 3,149; copy number 2: 54,143; copy number 3: 1,206; copy number 4: 108; copy number 5: 80; copy number 6: 23; copy number 7: 99; copy number 8: 77; copy number 13: 11.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,309,230–90,315,836, 2 genes: AC233263.2, IGKV1OR2-118.
- chr7:140,672,945–140,696,261, 1 gene (within-gene range 0–2): ADCK2.
- chr7:140,695,336–140,697,077, 1 gene (within-gene range 0–2): NDUFB2-AS1.
- chr10:11,849,608–11,894,700, 1 gene (within-gene range 0–2): PROSER2-AS1.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr22:30,285,117–30,299,482, 2 genes (within-gene range 0–2): CASTOR1, AC004997.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 265 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:54,948,015–55,378,797, 19 genes, copy number 7: TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P.
- chr12:57,546,026–59,064,238, 47 genes, copy number 7–8 (within-gene range 2–8): KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1.
- chr12:59,523,278–60,419,293, 11 genes, copy number 5: LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:61,708,259–62,279,150, 1 gene, copy number 7 (within-gene range 3–7): TAFA2.
- chr12:61,879,318–67,096,410, 115 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr12:68,248,242–69,610,907, 43 genes, copy number 7–13: IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10.
- chr12:69,738,860–71,586,310, 23 genes, copy number 6 (within-gene range 2–6): RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1.
- chr14:105,647,924–105,649,057, 1 gene, copy number 7: COPDA1.
- chr22:50,738,196–50,801,309, 5 genes, copy number 5: ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 322. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
